Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-AA5H, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-AA5H-01A (Primary Tumor).

[page 1 of 3]
Specimen Comments

SPECIMEN

- A. Bladder, ovaries, uterus, fallopian tubes and cervix.
- B. Left external iliac node.
- C. Left obturator node.
- D. Left common iliac node.
- E. Right external iliac node.
- F. Right common iliac node.
- G. Right obturator node.
- H. Left ureteric margin.
- I. Right ureteric margin.

ICD O-3

Carcinoma, urothelial NOS 8120/3

Site Bladder NOS C67.9

Ja 4/30/14

CLINICAL DETAILS

Invasive bladder cancer. Clinically nodes into 2. G3 pT2 N2.

MACROSCOPY

A. Radical cystectomy with hysterectomy and salpingo-oophorectomy including cervix. The bladder measuring 85 mm superior-inferior x 61 mm medial-lateral x 53 mm anterior-posterior with attached fat up to 115 mm. The uterus measures 68x45x32 mm, right fallopian tube 42 mm x 5 mm with right ovary measuring 21x13x12 mm, left fallopian tube measures 47 mm x 6 mm diameter with left ovary 21x12x9 mm. Ovaries and tubes unremarkable. There is a subserosal nodule measuring 11 mm in uterine body. Few surface fibroids seen. The perivesicle fat and peritoneum is unremarkable does not contain tumour. The cervix is unremarkable.

On sectioning the bladder, there is a firm white solid lesion on the right lateral side extending to dome and left lateral side measuring 40x20x47 mm. The lesion goes through the wall extending to perivesicular fat.

Block Key

1 = Urethra resection margin, 2 = Right lateral aspect of tumour, full thickness with perivesicular fat, 3+4 = Composite tumour through vesicular wall and fat and left dome, 5+6 = Composite tumour through vesicular wall and fat, left side and dome, 7 = Tumour with perivesicular fat, 8 = Tumour perivesicular fat, tumour interface with non-affected mucosa, 9 = Trigone, 10 = Right lateral not affected mucosa, 11 = Left lateral not affected mucosa, 12 = Cervix and lower uterine segment, 13 = Uterus body, 14 = Cervix with lower uterine segment, 15 = Right adnexa, 16 = Left adnexa, 17 = Lymph node ? a deposit 7 mm across was in right perauricular fat away from main tumour, 18 = ?separate deposit of tumour on left side perauricular fat.

B. Fatty tissue measuring 81x32x10 mm. (One lymph node 17 mm in 1 & 2, 3 = ? lymph node).

C. A piece of fatty tissue with node measuring 95x20x7 mm. Lymph node measuring 13 mm (blocks 1) lymph node measuring 27 mm (blocks 2 + 3), lymph node measuring 19 mm (block 4) another lymph node 5 mm across (block 5).

D. A piece of fatty tissue measuring 17 mm across containing lymph node measuring 7 mm across.

E. Fibrous tissue with lymph node measuring 35x23x7 mm. Lymph node measuring 20 mm across grossly involved.

[page 2 of 3]
F. 2 pieces of fibrofatty tissue the larger measuring 25x12 mm, the smaller measuring 15x8 mm. There is a 15 mm lymph node (block 1). Another lymph node 10 mm across (block 2).

G. A piece of fibrofatty tissue measuring 85x25x13 mm, 25 mm lymph node involved (block 1) and a lymph node of 9 mm (block 2) and a 12 mm lymph node (block 3).

H. Tube measuring 9 mm length x 4 mm diameter.

I. Tube with fibrous tissue measuring 13 mm in length x 3 mm in diameter, with fibrous tissue up to 11 mm.

MICROSCOPY

A. Bladder, ovaries, uterus, fallopian tubes and cervix; Sections from the macroscopically identified lesion confirm a poorly differentiated solid urothelial carcinoma arising from surface carcinoma in situ and extending the full thickness of the bladder wall to extend into the perivesicle fat.

The tumour invades with broad fronts and does not elicit a lymphocytic infiltrate at the tumour host interface. Lymphovascular invasion is frequent.

There is occasional perineural invasion.

The tumour extends to within 4 mm of the circumferential surgical resection margin. The background bladder wall is within morphologically normal limits.

The urethral surgical resection margin shows squamous metaplasia only. Bladder wall also contains a mesonephric duct remnant.

The tumour cells themselves are markedly pleomorphic and have moderate amounts of eosinophilic cytoplasm. There are numerous admixed giant cells some which are osteoclastic type. They do not have trophoblastic differentiation. No background sarcomatoid change or heterologous elements are noted.

The sections of the uterus and cervix confirm inactive endometrium, two subserosal small leiomyomas, normal cervix and normal adenexae.

The nodule identified separately in the remnant fat away from the main specimen is a lymph node with metastatic carcinoma with extracapsular extension.

B. Left external iliac node; A single lymph node with no evidence of metastatic carcinoma.

C. Left obturator lymph node; Three lymph nodes, one with metastatic carcinoma. The deposit measures 7 mm in maximum dimension and there is no extracapsular extension.

D. Left common iliac node; A single lymph node with no evidence of metastatic carcinoma.

E. Right external iliac node; A single node with metastatic carcinoma. The deposit measures 10 mm and there is no extracapsular extension.

F. Right common iliac node; Two lymph nodes with no evidence of metastatic carcinoma.

G. Right obturator node; Three lymph nodes, one with metastatic carcinoma. The deposit measures 6 mm and there is extracapsular extension into the hilar soft tissue.

H & I; This is ureteric tissue within normal limits.

SUMMARY

Parts A-I

Bladder : Poorly differentiated urothelial carcinoma pT3b pN2 R0.

Ref:

Pathologists -

[page 3 of 3]
DR

Source: NCI Genomic Data Commons file 09ecde52-8ea2-4b77-9c28-bc7eb3fe96c1 (TCGA-ZF-AA5H.34430EB2-DC78-41EC-A4BD-9452B1B01C92.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).